CCDI case PBBSLV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/61ee15d4-6de0-488f-8120-1c9a46a55a73

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Myofibroblastic tumor, NOS: ICD-O-3 morphology code: 8825/1; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 6.3 years (2,310 days).

Biospecimens (3 samples)
- Sample 0DGQAI: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DGQAM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGQBF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
